TARGET case TARGET-30-PARJXH — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/216dba90-19ff-565c-9bf2-01889de8cfbe

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: Age at diagnosis: 2.4 years (881 days); Days to last follow up: 2,760 days (7.6 years); INSS stage: Stage 4.
